Gene-level copy-number profile of tumor specimen REBC-ADKE-TTP1-A from REBC case REBC-ADKE, project REBC-THYR (Comprehensive genomic characterization of radiation-related papillary thyroid cancer in the Ukraine). Sex at birth: female; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland.
Specimen REBC-ADKE-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 0a718aad-3184-4096-b086-c6465fef23f0.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator REBC-ADKE-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,228 have no estimate.
https://portal.gdc.cancer.gov/files/51da970c-bd86-42f0-9556-6ae61d9cbcfd

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 382; copy number 2: 57,994; copy number 3: 12; copy number 5: 7.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 7 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr15:88,989,519–89,202,355, 7 genes, copy number 5 (within-gene range 2–5): AC107954.1, AC013565.2, AC013565.1, AC013565.3, ABHD2, RNU7-195P, HMGB1P8.

Autosomal genes at a single copy (total copy number 1): 382. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
